Somatic mutation profile of tumor specimen TCGA-BA-A6DB-01A (aliquot TCGA-BA-A6DB-01A-11D-A30E-08) from TCGA case TCGA-BA-A6DB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 24.6 years (8,967 days).
Specimen TCGA-BA-A6DB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95972394-ba03-4fec-be48-96c6b5a5dffe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A6DB-10A (Blood Derived Normal), aliquot TCGA-BA-A6DB-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fffe78f5-5b0c-4761-9874-c3a5092f39b7

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPK3 | c.2374G>C p.G792R | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV99361037; called by muse, mutect2
- ANGPTL3 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV99224703; called by muse, mutect2
- LPIN2 | c.2399C>T p.P800L | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs748431474, COSV99858448; ClinVar: uncertain significance; called by muse, mutect2
- MINAR1 | c.2404C>T p.L802F | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV59581678, COSV59585822; called by muse, mutect2
- MTUS2 | c.2411C>A p.T804K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV70918809; called by muse, mutect2
- NCOA3 | c.2630C>T p.P877L | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs759317681; called by muse, mutect2
- PCLO | c.992C>G p.P331R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.081); catalogued as COSV100433328; called by muse, mutect2
- PRCP | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs747931538, COSV100476039; called by muse, mutect2, varscan2
- PRR5 | c.1105C>T p.R369W (on ENST00000336985 / NM_181333.4; = p.R360W on NM_015366.4) | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs780690639, COSV99134429; called by muse, mutect2
- TNFAIP8 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99174272; called by muse, mutect2, varscan2
- TRPM7 | c.4529A>G p.E1510G | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV100539923; called by muse, mutect2
- ZNF875 | c.1712A>T p.H571L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746467134, COSV100183354, COSV60990136; called by muse, mutect2, varscan2
- KCNB2 | c.510C>A p.T170= | Silent (SNP) | VAF 21/241 reads (9%) | catalogued as COSV101578806; called by muse, mutect2
- KLHL6 | c.1392C>T p.T464= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV100384704; called by muse, mutect2, varscan2
- RFPL4B | c.429C>T p.S143= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs763866681, COSV101480700; called by muse, mutect2
- ZMPSTE24 | c.1305A>G p.L435= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as COSV101031998; called by muse, mutect2, varscan2
